Gene-level copy-number profile of tumor specimen ALCH-B37Z-TTP1-A from ALCHEMIST case ALCH-B37Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.9 years (23,327 days).
Specimen ALCH-B37Z-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9f0acd42-eb06-4f4d-97dd-15eda7279d15.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B37Z-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/79fb3614-7dff-4b18-a12f-854c4130785e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 3,546; copy number 2: 54,528; copy number 3: 563; copy number 4: 84; copy number 5: 49; copy number 6: 11; copy number 7: 22; copy number 8: 11; copy number 9: 4; copy number 10: 8; copy number 12: 3; copy number 13: 1; copy number 14: 2; copy number 15: 3; copy number 16: 1; copy number 18: 1; copy number 19: 2; copy number 20: 2; copy number 22: 2; copy number 30: 3.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,863,159–22,863,226, 1 gene (within-gene range 0–2): MIR4253.
- chr2:45,013,214–45,013,668, 1 gene: AC093702.1.
- chr3:130,089,433–130,094,304, 1 gene (within-gene range 0–2): LINC02014.
- chr9:63,719,864–63,720,441, 1 gene: CDRT15P7.
- chr9:63,729,702–63,730,173, 1 gene (within-gene range 0–1): AL772155.2.
- chr10:68,544,489–68,544,833, 1 gene: TMEM14DP.
- chr11:127,204–139,612, 1 gene (within-gene range 0–6): LINC01001.
- chr11:2,129,121–2,129,964, 1 gene (within-gene range 0–3): AC132217.1.
- chr11:71,453,109–71,539,209, 5 genes (within-gene range 0–2): NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8.
- chr12:132,275,391–132,284,606, 4 genes (within-gene range 0–2): AC148477.3, AC148477.2, AC148477.5, AC148477.4.
- chr16:668,105–674,174, 1 gene (within-gene range 0–4): RHOT2.
- chr16:1,065,240–1,066,502, 1 gene (within-gene range 0–3): AC009041.2.
- chr16:1,358,900–1,361,405, 1 gene (within-gene range 0–1): AL031709.1.
- chr16:2,223,580–2,235,742, 1 gene (within-gene range 0–20): E4F1.
- chr16:89,919,165–89,972,832, 5 genes (within-gene range 0–2): AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1.
- chr19:3,521,248–3,521,320, 1 gene (within-gene range 0–1): AC005787.1.
- chr22:18,077,920–18,146,554, 6 genes (within-gene range 0–2): PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1.
- chr22:50,691,260–50,691,363, 1 gene (within-gene range 0–2): RNU6-409P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 125 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–2,530,263, 5 genes, copy number 5–7: PLCH2, AL139246.1, AL139246.4, PANK4, HES5.
- chr1:2,549,920–2,569,888, 3 genes, copy number 5–7: TNFRSF14-AS1, TNFRSF14, AL139246.2.
- chr1:2,632,568–2,636,620, 1 gene, copy number 5 (within-gene range 2–5): MMEL1-AS1.
- chr3:184,230,429–184,242,329, 2 genes, copy number 5 (within-gene range 1–5): VWA5B2, MIR1224.
- chr5:892,884–919,357, 2 genes, copy number 5: TRIP13, AC122719.3.
- chr8:143,915,153–143,976,734, 2 genes, copy number 8 (within-gene range 8–24): PLEC, MIR661.
- chr8:144,049,079–144,086,216, 7 genes, copy number 5–18: SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1.
- chr9:136,494,433–136,549,893, 5 genes, copy number 7: NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1.
- chr9:136,796,338–136,810,042, 2 genes, copy number 30 (within-gene range 1–30): CCDC183, AL355987.4.
- chr9:136,844,415–136,860,799, 3 genes, copy number 8–13 (within-gene range 2–16): AJM1, PHPT1, MAMDC4.
- chr9:136,975,092–136,985,435, 2 genes, copy number 6 (within-gene range 4–6): PTGDS, AL807752.7.
- chr9:136,994,608–137,046,179, 6 genes, copy number 5–16: CLIC3, ABCA2, C9orf139, FUT7, AL807752.6, NPDC1.
- chr9:137,057,663–137,070,557, 3 genes, copy number 5–10: AL807752.2, SAPCD2, AL807752.3.
- chr11:112,967–126,123, 2 genes, copy number 22: AC069287.1, CICP23.
- chr11:167,784–207,428, 3 genes, copy number 6 (within-gene range 1–10): BET1L, SCGB1C1, ODF3.
- chr11:837,356–842,529, 1 gene, copy number 5 (within-gene range 3–5): POLR2L.
- chr11:1,012,823–1,036,718, 1 gene, copy number 7: MUC6.
- chr11:1,074,875–1,201,138, 2 genes, copy number 6–8: MUC2, MUC5AC.
- chr11:1,734,821–1,764,573, 3 genes, copy number 7–8 (within-gene range 1–8): AC068580.4, CTSD, AC068580.3.
- chr11:1,776,930–1,778,388, 1 gene, copy number 14: AC068580.2.
- chr11:1,850,904–1,892,267, 5 genes, copy number 5: LSP1, MIR4298, AC051649.1, MIR7847, PRR33.
- chr14:104,769,349–104,804,712, 2 genes, copy number 6–10 (within-gene range 2–10): AKT1, ZBTB42.
- chr14:104,857,792–104,858,836, 1 gene, copy number 7: AL583810.1.
- chr14:105,664,633–105,669,843, 1 gene, copy number 7 (within-gene range 2–7): IGHGP.
- chr16:525,155–527,407, 1 gene, copy number 9: LINC00235.
- chr16:629,239–667,833, 6 genes, copy number 10–19 (within-gene range 3–19): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2.
- chr16:684,622–692,554, 2 genes, copy number 7 (within-gene range 1–17): WDR24, Z92544.1.
- chr16:720,581–741,329, 4 genes, copy number 6–8 (within-gene range 4–8): ANTKMT, CCDC78, HAGHL, CIAO3.
- chr16:788,046–800,737, 2 genes, copy number 9 (within-gene range 3–9): CHTF18, GNG13.
- chr16:1,101,260–1,113,399, 2 genes, copy number 5–12: AL031713.1, AL031598.1.
- chr16:1,305,547–1,309,413, 1 gene, copy number 10 (within-gene range 2–10): AC120498.9.
- chr16:1,333,638–1,351,878, 2 genes, copy number 8: BAIAP3, TSR3.
- chr16:2,235,689–2,238,711, 2 genes, copy number 20 (within-gene range 0–20): AC009065.1, DNASE1L2.
- chr16:88,382,959–88,537,031, 4 genes, copy number 5–7: ZNF469, ZFPM1, MIR5189, AC116552.1.
- chr16:88,856,220–88,866,660, 2 genes, copy number 5: TRAPPC2L, PABPN1L.
- chr17:82,290,046–82,317,608, 3 genes, copy number 5–15: LINC01970, AC132872.1, CD7.
- chr19:2,230,084–2,273,490, 8 genes, copy number 5–7 (within-gene range 3–7): PLEKHJ1, MIR1227, MIR6789, SF3A2, AMH, MIR4321, JSRP1, OAZ1.
- chr20:62,796,473–62,805,587, 2 genes, copy number 5 (within-gene range 4–5): MRGBP, OGFR-AS1.
- chr20:63,520,765–63,574,239, 4 genes, copy number 5–12: PPDPF, PTK6, FNDC11, HELZ2.
- chr22:20,129,456–20,313,216, 5 genes, copy number 5–7: ZDHHC8, CCDC188, AC007663.2, LINC00896, AC007663.1.

Autosomal genes at a single copy (total copy number 1): 690. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
